Somatic mutation profile of tumor specimen MMRF_1486_1_BM_CD138pos (aliquot MMRF_1486_1_BM_CD138pos_T1_KBS5U_L05771) from MMRF case MMRF_1486, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.4 years (20,589 days).
Specimen MMRF_1486_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a924a37-6298-4f66-98c8-a0b5fd3c3984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1486_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1486_1_PB_Whole_C2_KBS5U_L05791; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f22f6d52-ef40-4cbb-a9d2-cebb3bbea440

The open-access MAF lists 58 somatic variants for this specimen: 23 protein-altering or splice-affecting, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 20, Intron 7, 5'UTR 3, RNA 2, 5'Flank 2, Splice Region 1, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7265C>T p.P2422L (on ENST00000272895 / NM_173076.3; = p.P2104L on NM_015657.3) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765289715, COSV55949978; called by muse, mutect2, varscan2
- CDCA7 | c.948G>A p.P316= (on ENST00000347703 / NM_145810.3; = p.P395= on NM_031942.5) | Splice Region (SNP) | VAF 11/113 reads (10%) | catalogued as rs1437714555; called by muse, mutect2, varscan2
- CSMD3 | c.6893G>T p.G2298V (on ENST00000297405 / NM_001363185.1; = p.G2194V on NM_052900.3) | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189454471, COSV52252143; called by muse, mutect2
- DLAT | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.055); catalogued as COSV54769289; called by muse, mutect2, varscan2
- EVPL | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56911043; called by muse, mutect2
- GLRX5 | c.212A>T p.N71I | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58763241; called by muse, mutect2, varscan2
- IGHJ6 | c.36A>T p.K12N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | PolyPhen benign (0); catalogued as rs377600355; called by muse, varscan2
- IGLV2-23 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.389); catalogued as rs1445237036; called by muse, mutect2, varscan2
- PCDHA11 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV56542290; called by muse, mutect2
- SDC3 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs374857118; called by muse, mutect2, varscan2
- VASN | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1288526677, COSV52027934; called by muse, mutect2
- DIAPH3 | c.1490T>A p.I497K (on ENST00000400324 / NM_001042517.2; = p.I234K on NM_030932.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- DNAH7 | c.1254G>C p.E418D | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- GNB2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- IGHV2-70D | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- IL17RE | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP4 | c.2069A>G p.N690S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MLXIP | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); called by muse, mutect2
- MRPS9 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- PHKG1 | c.287C>G p.T96S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- PKD1L3 | c.2612G>A p.R871K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PLCH1 | c.4852A>T p.K1618* (on ENST00000340059 / NM_001130960.2; = p.K1610* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/212 reads (27%) | called by muse, mutect2, varscan2
- ZNF385C | c.529dup p.Y177Lfs*2 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | called by mutect2, varscan2
- ABCD1 | c.*697C>T | 3'UTR (SNP) | VAF 10/11 reads (91%) | catalogued as rs1367494104; called by muse, mutect2
- AC016526.2 | n.245+2171A>C | Intron (SNP) | VAF 87/144 reads (60%) | called by muse, mutect2, varscan2
- ACTL10 | c.-134T>A | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- AP001781.2 | c.-145C>A | 5'UTR (SNP) | VAF 16/127 reads (13%) | catalogued as rs1218951163; called by muse, mutect2, varscan2
- ATRX | c.*219G>C | 3'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 16/62 reads (26%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BCL7A | chr12:122021454 T>C | 5'Flank (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- CACNG8 | c.*6785T>C | 3'UTR (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- CAV2 | c.*615C>T | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- CEP44 | c.*552G>A | 3'UTR (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- COL4A4 | c.*3910C>T | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- DERL2 | c.*3380G>A | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- DISC1 | c.*415C>T | 3'UTR (SNP) | VAF 56/116 reads (48%) | called by muse, mutect2, varscan2
- FAM27E5 | n.113T>C | RNA (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- GBP3 | c.*102A>G | 3'UTR (SNP) | VAF 45/119 reads (38%) | catalogued as rs961598345; called by muse, mutect2, varscan2
- GPC5 | c.1561+345196G>A | Intron (SNP) | VAF 3/17 reads (18%) | catalogued as rs1033163451; called by muse, mutect2
- GRPEL1 | c.*39T>C | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- INHBA | c.*2874C>T | 3'UTR (SNP) | VAF 4/84 reads (5%) | catalogued as rs1193953138; called by muse, mutect2
- MYLK3 | c.2115-896G>A | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- OR2U1P | n.719C>A | RNA (SNP) | VAF 11/145 reads (8%) | catalogued as rs1406692809; called by muse, mutect2
- OXNAD1 | c.*114G>T | 3'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1210G>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as rs928116305; called by muse, mutect2, varscan2
- PLA2G4E | c.-119T>C | 5'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- PRTG | c.*5776C>T | 3'UTR (SNP) | VAF 24/81 reads (30%) | catalogued as rs1036756120; called by muse, mutect2, varscan2
- PTEN | c.*920C>T | 3'UTR (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- RAB17 | c.158-131C>T | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as rs1232289792; called by muse, mutect2
- SCMH1 | c.*434del | 3'UTR (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- SFTPA2 | c.*448A>C | 3'UTR (SNP) | VAF 32/114 reads (28%) | called by muse, varscan2
- SGMS1 | c.*1244T>C | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- SLC15A2 | c.*1610T>C | 3'UTR (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- SNORD115-41 | chr15:25247209 G>A | 3'Flank (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- STXBP6 | c.*1764T>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- TJP2 | c.61-7457C>T | Intron (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2
- ZNF445 | c.429+159G>T | Intron (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- ZNF780B | c.*3272A>T | 3'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
